Somatic mutation profile of tumor specimen TARGET-10-PASZIY-09A (aliquot TARGET-10-PASZIY-09A-01D) from TARGET case TARGET-10-PASZIY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,234 days).
Specimen TARGET-10-PASZIY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b149e5a-60a6-411e-a245-dcc9a559d716.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASZIY-10A (Blood Derived Normal), aliquot TARGET-10-PASZIY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70f2b51f-46ae-43a8-aeb7-e2d96d6adfeb

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, RNA 1, Intron 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 69/147 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1260144256, COSV56302720; called by muse, mutect2, varscan2
- ATG4B | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs575560117, COSV60353647; called by muse, mutect2, varscan2
- BAG3 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV64842892; called by muse, mutect2, varscan2
- BLMH | c.313T>G p.W105G | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55587541; called by muse, mutect2, varscan2
- CDKN2C | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52956240; called by muse, mutect2, varscan2
- FAM160A1 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70710099; called by muse, mutect2, varscan2
- FAM47B | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61455930; called by muse, mutect2, varscan2
- GRK2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57954777; called by muse, mutect2, varscan2
- KDM6A | c.3328_3339del p.V1110_V1113del | In Frame Del (DEL) | VAF 14/16 reads (88%) | catalogued as COSV65048405; called by mutect2, pindel*, varscan2
- KIFC3 | c.2387C>A p.T796K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs554025520, COSV65548640, COSV65553898; called by muse, mutect2, varscan2
- KRTAP24-1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV61090338; called by muse, mutect2, varscan2
- LAMA1 | c.3812A>T p.Y1271F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV67546120; called by muse, varscan2
- LRRK2 | c.4447C>T p.R1483* | Nonsense Mutation (SNP) | VAF 41/78 reads (53%) | catalogued as rs114908017, COSV100110983, COSV54153930; called by muse, mutect2, varscan2
- RHBDF2 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs780237997, COSV57423882; called by muse, mutect2, varscan2
- RYR2 | c.4498C>T p.R1500C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs778394498, COSV63680185; called by muse, mutect2, varscan2
- SRGAP1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs770426933, COSV100754444, COSV61905154; called by muse, mutect2, varscan2
- TBC1D8B | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 59/68 reads (87%) | catalogued as COSV52185134; called by muse, mutect2, varscan2
- TMEM151A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59175822; called by muse, mutect2
- ARL6IP5 | c.293_300dup p.F101Pfs*35 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | called by mutect2, varscan2
- DNM2 | c.2345del p.P782Qfs*3 (on ENST00000355667 / NM_001005360.3; = p.P778Qfs*3 on NM_004945.3) | Frame Shift Del (DEL) | VAF 32/66 reads (48%) | called by mutect2, pindel, varscan2
- KMT2E | c.187-8_187-5delinsAGGGTTCTAACCCC p.X63_splice | Splice Site (INS) | VAF 41/80 reads (51%) | called by pindel, varscan2*
- MEMO1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZBTB1 | c.2071T>C p.C691R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CSPG4 | c.1929C>T p.S643= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs747775802; called by muse, varscan2
- KATNB1 | c.1674C>T p.T558= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs200775005; called by muse, mutect2, varscan2
- QPRT | c.372C>T p.A124= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs772757445; called by muse, varscan2
- RP1 | c.603G>A p.T201= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV55114043; called by muse, mutect2, varscan2
- RSPH6A | c.1158G>A p.A386= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs150763678, COSV99679861; called by muse, varscan2
- TNFRSF11B | c.828C>T p.L276= | Silent (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- ZNF837 | c.822C>T p.D274= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs1021460614; called by muse, mutect2, varscan2
- AL031777.2 | c.*331A>G | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- GAD1 | c.639-1436G>A | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- MST1L | n.1982G>A | RNA (SNP) | VAF 27/36 reads (75%) | catalogued as rs1157314902; called by muse, mutect2, varscan2
